Surgical pathology report (de-identified scan), TCGA case TCGA-V7-A7HQ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-V7-A7HQ-01A (Primary Tumor).

[page 1 of 4]
Surgical Final Report

Temporary Copy

Case # [REDACTED]
Collected [REDACTED]
Ordered by [REDACTED]

Final Pathologic Diagnosis

CORRECTED REPORT:

A) SENTINEL NODE #1 (EXCISION):

- One lymph node involved by metastatic carcinoma (1/1).

B) SENTINEL NODE #2 (EXCISION):

- One out of two lymph nodes, involved by metastatic carcinoma (micrometastases) (1/2).

C) SENTINEL LYMPH NODE #3 (EXCISION):

- One out of two lymph nodes, involved by metastatic carcinoma (micrometastases) (1/2).

D) RIGHT BREAST (MASTECTOMY):

- Invasive ductal carcinoma, Nottingham grade 2.
- See synoptic report.

E) NEW INFERIOR MARGIN (EXCISION):

- Breast tissue with benign fibrocystic changes, including ductal hyperplasia and apocrine metaplasia.
- Negative for malignancy.

NOTE: This corrected report is being issued due to a typographical error in the original report.
The initial diagnosis rendered by [REDACTED] remains unchanged.

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Synoptic Report

D: BREAST, MASTECTOMY -

SPECIMEN TYPE:

Mastectomy

LYMPH NODE SAMPLING:

Sentinel lymph node with axillary dissection

SPECIMEN SIZE:

ICD-O-3

Carcinoma, infiltrating duct NOS 8500/3

Site ^{CSCF} (R) Breast NOS C50.9

^{path} (R) Breast, lower outer quadrant C50.5

JW 9/25/13

[page 2 of 4]
Surgical Final Report

Temporary Copy

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Patient: [REDACTED]
ID: [REDACTED]
Location: [REDACTED]

Greatest dimension: 30 cm

*Additional dimensions: 7.0 x 2.5

LATERALITY:

Right

TUMOR SITE:

Lower outer quadrant

SIZE OF INVASIVE COMPONENT:

Greatest dimension: 2.0 cm

*Additional dimensions: 1.5 x 1.0 cm

Two separate lesions were present, each one measuring 2.0 x 1.5 x 1.0 cm.

HISTOLOGIC TYPE:

Ductal carcinoma in situ

Invasive ductal carcinoma

HISTOLOGIC GRADE:

Tubule formation: Moderate 10% to 75% (score = 2)

Nuclear pleomorphism: Marked variation in size, nucleoli, chromatin clumping, etc. (score = 3)

0 to 5 mitoses per 10 HPF (score = 1)

Nottingham Grade II: 6-7 points

PRIMARY TUMOR (pT):

pT1c: Tumor more than 1.0 cm but not more than 2.0 cm in greatest dimension

REGIONAL LYMPH NODES (pN):

pN2a: Metastasis in 4 to 9 axillary lymph nodes (at least 1 tumor deposit greater than 2.0 mm)

Number examined: 18

Number involved: 5

DISTANT METASTASIS (M):

pMX: Cannot be assessed

MARGINS:

Margin(s) involved by invasive carcinoma

Specify which margin(s): Inferior margin at mastectomy (specimen D). See comment.

*EXTENT OF MARGIN INVOLVEMENT FOR INVASIVE CARCINOMA

*VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

*Present

*MICROCALCIFICATIONS:

*Present in DCIS

*ADDITIONAL PATHOLOGIC FINDINGS:

Fibrocystic changes, biopsy site related changes, and columnar cell hyperplasia.

*COMMENT(S):

The inferior margin is involved by carcinoma in the mastectomy specimen (specimen D), however, additionally submitted inferior resection margin is not involved (specimen E). Clinical correlation is necessary for interpretation of these findings.

Diagnostic Comment

According to previous biopsy, 65% of tumor cells show moderate to strong nuclear staining for estrogen receptors, 80% of tumor cells show nuclear staining show strong nuclear staining for progesterone receptors, and Her2-neu gene is not amplified by FISH (please see report

[page 3 of 4]
Surgical Final Report

Temporary Copy

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

Patient: [REDACTED]

ID: [REDACTED]

Location: [REDACTED]

Intraoperative Diagnosis

TP A1: Touch prep positive for carcinoma. No frozen done.

TP B1: No touch preps done because first sentinel lymph node is positive.

TP C1: No touch preps done because first sentinel lymph node is positive.

Clinical History

year old female with breast cancer.

Pre/Post-operative Diagnosis

Breast cancer.

Gross Anatomic Description

(SPECIMEN D: Dictated by

(SPECIMENS A-C and E: Dictated by

Specimens received in five containers.

Specimen A: Designated "sentinel node #1" is received fresh for intraoperative consultation on labeled with the patient's name and "sentinel node #1". Specimen consists one piece of yellow tissue measuring 1.2 x 1.0 x 0.6 cm. The lymph node is bisected. Touch prep is done. No frozen section is performed.

Section code: A1 - two pieces, one lymph node, entire specimen.

Specimen B: Designated "sentinel node #2" is received fresh for intraoperative consultation on labeled with the patient's name and "sentinel node #2". Specimen consists of one yellow/tan irregular fragment of tissue measuring 0.8 x 0.6 x 0.3 cm. No intraoperative procedure performed. Entirely submitted for permanent sections.

Section code: B1 - entire specimen.

Specimen C: Designated "sentinel node #3" is received fresh for intraoperative consultation on labeled with the patient's name and "sentinel node #3". Specimen consists of one yellow/tan fatty fragment of tissue measuring 0.8 x 0.4 x 0.4 cm. The specimen is bisected revealing one lymph node. No intraoperative procedure performed. Entirely submitted for permanent sections.

Section code: C1 - two pieces, one lymph node, entire specimen.

Specimen D: Designated "right mastectomy (stitch on lateral margin, clip on apex of dissection)" is received fresh for Tumor Bank on labeled with the patient's name, MRN and "right mastectomy (stitch on lateral margin, clip on apex of dissection)". Specimen consists of one right radical mastectomy with attached axillary tail weighing 220.8 g. The specimen measures 30.0 x 7.0 x 2.5 cm. The axillary tail measures 13.0 x 3.5 x 2.0 cm. The breast measures 17.0 x 6.0 x 2.5 cm. There is an overlying ellipse of tan wrinkled skin measuring 15.0 x 6.0 cm. There is an unremarkable nipple measuring 1.5 cm in diameter and 0.5 cm in thickness. The areola measures 4.0 x 3.5 cm and is unremarkable. The external palpation of skin reveals two firm masses which are inferior lateral to the nipple, at the outer lower quadrant. One is at 3.5 cm from the nipple and the other is at 2.0 cm from the nipple. The suture is identified which denotes the lateral margin. Cut surface reveals two white/tan spiculated tumors. The medial tumor measures 2.0 x 1.5 x 1.0 cm with what appears to be a previous biopsy site. The more lateral tumor mass measures 2.0 x 1.5 x 1.0 cm and also appears to have a previous biopsy site. The tumor masses appear to be connected by a white/tan tract of tumor

[page 4 of 4]
Surgical Final Report**Temporary Copy**

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

Patient: [REDACTED]

ID: [REDACTED]

Location: [REDACTED]

measuring 0.5 x 0.2 x 0.2 cm. The lateral tumor comes within <0.1 cm of the inferior margin and 0.2 cm of the deep margin. The medial tumor comes within 0.1 cm of the inferior margin and appears to abut the deep margin. Both tumors are >3.0 cm from the superior and medial margins. The remainder of the cut sections are grossly unremarkable as yellow/tan fatty fibrous tissue. There is a free floating fragment of breast tissue measuring 8.5 x 1.5 x 0.5 cm with a staple denoting the medial position. The fragment weighs 3.9 g. This fragment is oriented with the assistance of [REDACTED] and according to him, it represents the deep margin. The fragment is oriented regarding lateral and medial aspects. The axillary tail is dissected and eleven lymph nodes are identified. The lateral tumor comes within ~0.2 cm of skin and the medial tumor comes within 1.0 cm of skin.

Inking code - breast: Green - superior portion of breast; Blue - inferior portion of breast; Black - deep portion of breast; Orange - area of further resection, inferiorly, adjacent to additional inferior margin (specimen E).

Inking code - additional fragment of tissue (deep margin): Black - entire external surface of free deep fragment; Green - medial tip of free deep fragment.

Section code: D1 - representative section of tumor closest to nipple; D2 - representative section of tumor farthest from nipple; D3 - tip of nipple, serially sectioned; D4 - remainder of nipple, en face; D5 - section of medial tumor with skin and orange margin; D6 - representative section of medial tumor with skin and orange margin; D7 - representative portion of tissue between described tumors to contain described tumor tract; D8 - representative section of lateral tumor with skin; D9-D10 - representative sections of lateral tumor with skin (sections through tumor were made from medial to lateral); D11-D12 - two representative sections of unremarkable breast tissue from medial inferior quadrant; D13-D14 - representative sections of unremarkable breast tissue from superior medial quadrant; D15-D16 - representative portions of unremarkable breast tissue from superior lateral quadrant; D17-D18 - representative sections of unremarkable breast tissue and lateral inferior quadrant; D19 - one lymph node, bisected; D20 - one lymph node, bisected; D21 - two lymph nodes submitted wholly with the more proximal node inked in black; D22 - two lymph nodes submitted wholly with the more proximal lymph node inked in black; D23 - one lymph node, bisected; D24 - two lymph nodes submitted wholly with the more proximal lymph node inked in black; D25 - two lymph nodes with the more proximal node inked in black (the lymph nodes were submitted from proximal to distal); D26 - inferior margin; D27 - lateral margin; D28 - medial margin; D29 - superior margin; D30 - deep posterior margin; D31-D36 - deep free fragments of breast tissue serially sectioned from medial to lateral.

Specimen E: Designated "new inferior margin" is received in formalin labeled with the patient's name and "new inferior margin". Specimen consists of one yellow/tan fatty fragment of tissue weighing 10.6 g and measuring 5.5 x 2.5 x 1.0 cm. The new inferior margin is inked in blue and the specimen is serially sectioned. Cut sections reveal a yellow/tan fatty interior that is grossly unremarkable. Section code: E1-E6 - entire specimen.

Source: NCI Genomic Data Commons file c18c4d87-f439-4f0e-9d8b-8bd83f25104f (TCGA-V7-A7HQ.82B46073-10CE-4D05-9421-6308E3FAD1AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).